Somatic mutation profile of tumor specimen MP2PRT-PAVAYW-TMP1-A (aliquot MP2PRT-PAVAYW-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVAYW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (887 days).
Specimen MP2PRT-PAVAYW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30713ff4-9e00-4baf-8dc7-c28c4e3ebb9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAYW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAYW-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da3e8e16-af51-413a-9d5c-44d28a67d13a

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 1, Intron 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 101/272 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1E | c.6854G>A p.R2285Q (on ENST00000367573 / NM_001205293.3; = p.R2242Q on NM_000721.4) | Missense Mutation (SNP) | VAF 146/439 reads (33%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.815); catalogued as rs775338609; called by muse, mutect2, varscan2
- NYAP1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 238/710 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as rs775435240; called by muse, mutect2, varscan2
- ABCC4 | c.3724G>A p.D1242N | Missense Mutation (SNP) | VAF 92/280 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- AC006059.2 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 112/346 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- CREBBP | c.4471_4472insGAC p.D1490_Q1491insR | In Frame Ins (INS) | VAF 117/342 reads (34%) | called by mutect2, pindel, varscan2
- TRIM69 | c.941T>G p.M314R (on ENST00000329464 / NM_182985.5; = p.M155R on NM_080745.5) | Missense Mutation (SNP) | VAF 104/327 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- VPS33A | c.296+1G>T p.X99_splice | Splice Site (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- ZNF816 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.062); called by muse, mutect2
- ZAN | c.909C>G p.L303= | Silent (SNP) | VAF 100/302 reads (33%) | called by muse, mutect2, varscan2
- DENND3 | c.-89-8dup | Intron (INS) | VAF 127/364 reads (35%) | called by mutect2, pindel, varscan2
